Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BJ, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BJ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:
Right chest wall mass.

Specimens Submitted:

- 1: Tissue above 1 st right rib posteriorly (fs)
- 2: Chest wall mass with ribs 1,2,3,4, right
- 3: Additional mass from right chest wall
- 4: Portion of right 4th rib posterior rib
- 5: Portion of right 3rd rib posterior rib
- 6: Portion of right 2nd rib posterior rib
- 7: Portion of right posterior rib 2 and 3

DIAGNOSIS:

1. Tissue above 1st right rib posteriorly, excision:
- High grade malignant fibrous histiocytoma, involving skeletal muscle.
2. Chest wall mass with ribs 1,2,3,4, right, en-bloc excision:
- High grade malignant fibrous histiocytoma.
- Tumor size: 8.8 x 7 x 4 cm.
- The tumor involves skeletal muscle, fibroadipose tissue, and erodes superficially into the bone (superior segment of rib).
- The tumor shows a highly infiltrative growth pattern.
- The tumor is predominantly viable, with only focal necrosis.
- Surgical margins are free of tumor.
3. Additional mass from right chest wall, excision:
- High grade malignant fibrous histiocytoma, present as multiple tissue fragments.
- The tumor involves skeletal muscle and fibroadipose tissue.
- The tumor shows focal reactive ossification.
4. Bone, portion of right 4th rib posterior rib, excision:
- Fragment of benign bony tissue and skeletal muscle.
5. Bone, portion of right 3rd rib posterior rib, excision:
- Fragment of benign bony tissue and skeletal muscle.
6. Bone, portion of right 2nd rib posterior rib, excision:
- Fragment of benign bony tissue and skeletal muscle.

** Continued on next page **

ICD O-3

Histiocytoma, fibrous malignant,
pleomorphic 8830/3

Site Chest NOS C49.3
9/21/22/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 5

7. Bone, portion of right posterior rib 2 and 3, excision:
- High grade malignant fibrous histiocytoma, involving skeletal muscle.

NOTE: THE INTERPRETATION OF THESE RESULTS IS BASED IN PART ON THE
DECALCIFICATION PROCEDURE PERFORMED.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled
"tissue above first right rib posteriorly" and consists of an irregular soft
tissue fragment measuring 3 x 2.4 x 0.8 cm. Sectioning reveals an
ill-defined, 1.2 cm tan, white mass. A representative section of mass is
submitted for frozen section. The remaining tissue is entirely submitted.

Summary of sections:
FSC - frozen section control
RT - remaining tissue

2. The specimen is received fresh labeled, "Chest wall mass with ribs
1,2,3,4, right", and consists of one portion of chest wall with three
segments of ribs measuring 14.5x9x5.5 cm. The three segments of ribs measure
8.0, 11.5 and 13.5 cm length from superior to inferior, respectively. The
superficial surface is inked blue and the deep surface is inked black. The
specimen is serially sectioned. The cut surface reveals one tan white firm
mass measuring 8.8x7x4 cm, involving superficial soft tissue and skeletal
muscle. The tumor is adjacent to the three segments of ribs but no gross
invasion into the bony tissue identified. Surgical margins are grossly free
of tumor. Representative sections of the specimen are submitted. TPS is
taken.

Summary of sections:
B1- two ends of rib 1, 8 cm
B2 - two ends of rib 2, 11.5 cm
B3 - two ends of rib 3, 13.5 cm
TB1 - tumor and rib 1, 8 cm
TB2- tumor and rib 2, 11.5 cm
TB3 - tumor and rib 3, 13.5 cm
SM - superficial margin and tumor
DM - deep margin and tumor
RS - tumor, representative

** Continued on next page **

Source: NCI Genomic Data Commons file db5d7403-abe7-4805-bfcb-2272099797d2 (TCGA-DX-A8BJ.00D5E8DE-EBBB-4895-B6D7-978522E00EA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).